Somatic mutation profile of tumor specimen TCGA-06-2562-01A (aliquot TCGA-06-2562-01A-01D-1494-08) from TCGA case TCGA-06-2562, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 81.5 years (29,753 days).
Specimen TCGA-06-2562-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 552f9d7e-e45a-4b8d-981c-d77b42ce630b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-2562-10A (Blood Derived Normal), aliquot TCGA-06-2562-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9ef716e0-da13-4464-b552-86067534f62d

The open-access MAF lists 63 somatic variants for this specimen: 44 protein-altering or splice-affecting, 16 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 16, Nonsense Mutation 3, Frame Shift Del 3, Intron 1, 3'UTR 1, 5'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.1400del p.T467Nfs*6 | Frame Shift Del (DEL) | VAF 15/87 reads (17%) | catalogued as rs1135402808, CM087524, COSV62197770; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ABCC8 | c.3760A>G p.I1254V | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.044); catalogued as COSV56846843; called by muse, mutect2, varscan2
- ABTB1 | c.946G>T p.G316C (on ENST00000232744 / NM_172027.3; = p.G174C on NM_032548.3) | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.526); catalogued as COSV51740062; called by muse, mutect2, varscan2
- ADAMTS2 | c.2821C>T p.R941C | Missense Mutation (SNP) | VAF 100/295 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as rs937744996, COSV52365650, COSV52367097; called by muse, mutect2, varscan2
- ADD2 | c.1657G>A p.V553M | Missense Mutation (SNP) | VAF 78/234 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.066); catalogued as COSV52455509; called by muse, mutect2, varscan2
- ATG5 | c.25C>T p.R9* | Nonsense Mutation (SNP) | VAF 66/223 reads (30%) | catalogued as COSV58346260; called by muse, mutect2, varscan2
- ATP8A1 | c.2091C>G p.H697Q | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs202148347, COSV52529474; called by muse, mutect2, varscan2
- CADM3 | c.244C>T p.R82* (on ENST00000368125 / NM_001127173.3; = p.R116* on NM_021189.5) | Nonsense Mutation (SNP) | VAF 7/147 reads (5%) | catalogued as rs1557936185, COSV63684355, COSV63687550; called by muse, mutect2
- CALN1 | c.565G>A p.V189I (on ENST00000329008 / NM_001017440.3; = p.V231I on NM_031468.4) | Missense Mutation (SNP) | VAF 47/182 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs144352678; called by muse, mutect2, varscan2
- CAPS2 | c.1532T>C p.I511T | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.044); catalogued as COSV60824159; called by muse, mutect2, varscan2
- CCSER1 | c.1544A>G p.D515G | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100394472, COSV61448997; called by muse, mutect2
- CTNND2 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.212); catalogued as COSV58868041; called by muse, mutect2, varscan2
- DNAH3 | c.3310G>A p.A1104T | Missense Mutation (SNP) | VAF 103/301 reads (34%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV54505767; called by muse, mutect2, varscan2
- EFNB2 | c.118T>G p.S40A | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV55363355; called by muse, mutect2
- HCLS1 | c.1399C>T p.R467W | Missense Mutation (SNP) | VAF 71/178 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs747473070, COSV57522166; called by muse, mutect2, varscan2
- KCNK10 | c.985A>G p.T329A | Missense Mutation (SNP) | VAF 94/258 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV56639817; called by muse, mutect2, varscan2
- LRIF1 | c.1036C>T p.R346* | Nonsense Mutation (SNP) | VAF 105/307 reads (34%) | catalogued as rs375319628; called by muse, varscan2
- LZTR1 | c.313T>C p.W105R | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53145505; called by muse, mutect2, varscan2
- MCF2 | c.2027T>C p.M676T | Missense Mutation (SNP) | VAF 92/125 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58478663; called by muse, mutect2, varscan2
- NECTIN4 | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.572); catalogued as COSV63511994; called by muse, mutect2, varscan2
- NF1 | c.4977_4980del p.K1661Gfs*36 (on ENST00000358273 / NM_001042492.3; = p.K1640Gfs*36 on NM_000267.3) | Frame Shift Del (DEL) | VAF 89/301 reads (30%) | catalogued as rs1085307459; called by mutect2, pindel, varscan2
- PDP2 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 66/161 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV61240096; called by muse, mutect2, varscan2
- PIK3R1 | c.1718T>C p.L573P (on ENST00000521381 / NM_181523.3; = p.L303P on NM_181504.4) | Missense Mutation (SNP) | VAF 64/206 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57124674; called by muse, mutect2, varscan2
- PKD1L1 | c.6766C>G p.L2256V | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV56971660; called by muse, mutect2, varscan2
- PNISR | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 70/236 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV65078777; called by muse, mutect2, varscan2
- PPEF2 | c.1198C>T p.R400W | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs779962909, COSV54420431, COSV54421273; called by muse, mutect2, varscan2
- PPP1R10 | c.2336G>A p.S779N | Missense Mutation (SNP) | VAF 144/379 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.01); catalogued as COSV64738555; called by muse, mutect2, varscan2
- PRPS1L1 | c.841A>G p.M281V | Missense Mutation (SNP) | VAF 163/532 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.021); catalogued as COSV72649948; called by muse, mutect2, varscan2
- PRR16 | c.479C>A p.P160Q (on ENST00000407149 / NM_001300783.2; = p.P137Q on NM_016644.2) | Missense Mutation (SNP) | VAF 64/166 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV65395149, COSV65399812; called by muse, mutect2, varscan2
- RNF43 | c.1800A>C p.R600S | Missense Mutation (SNP) | VAF 86/251 reads (34%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.018); catalogued as COSV68457003; called by muse, mutect2, varscan2
- SELE | c.1166G>A p.R389H | Missense Mutation (SNP) | VAF 74/213 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs139137736; called by muse, mutect2, varscan2
- SLC12A5 | c.1603G>A p.A535T (on ENST00000454036 / NM_001134771.2; = p.A512T on NM_020708.5) | Missense Mutation (SNP) | VAF 92/293 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV54789147; called by muse, mutect2, varscan2
- SLC46A2 | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 62/270 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV65289604; called by muse, mutect2, varscan2
- SLC4A4 | c.1228G>A p.G410R (on ENST00000264485 / NM_001098484.3; = p.G366R on NM_003759.4) | Missense Mutation (SNP) | VAF 45/141 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.14); catalogued as COSV52615891; called by muse, mutect2, varscan2
- SMG5 | c.1658A>G p.N553S | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.344); catalogued as rs151295845; called by muse, mutect2, varscan2
- SSTR4 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 79/348 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.532); catalogued as COSV54797114; called by muse, mutect2, varscan2
- TDG | c.819T>A p.S273R | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57167623; called by muse, mutect2
- TTN | c.61267A>G p.I20423V (on ENST00000591111; = p.I12999V on NM_003319.4) | Missense Mutation (SNP) | VAF 69/181 reads (38%) | PolyPhen benign (0.015); catalogued as COSV60194123; called by muse, mutect2, varscan2
- XCL1 | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.195); catalogued as rs141027416; called by muse, mutect2, varscan2
- ZAN | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs746268486, COSV61812094; called by muse, mutect2, varscan2
- ZIC4 | c.971C>T p.A324V | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as rs1036494828, COSV67170773, COSV67174229; called by muse, mutect2, varscan2
- ZNF100 | c.3+1G>A p.X1_splice | Splice Site (SNP) | VAF 77/227 reads (34%) | catalogued as COSV64167504; called by muse, mutect2, varscan2
- ZNF407 | c.5927C>T p.S1976L | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs750214167, COSV55254983; called by muse, mutect2, varscan2
- PLCB1 | c.475_479del p.L159Afs*26 | Frame Shift Del (DEL) | VAF 59/301 reads (20%) | called by mutect2, pindel, varscan2
- CDH7 | c.738A>G p.T246= | Silent (SNP) | VAF 32/85 reads (38%) | catalogued as COSV59882061; called by muse, mutect2, varscan2
- EPHB1 | c.2616G>A p.A872= | Silent (SNP) | VAF 25/79 reads (32%) | catalogued as rs760099232, COSV67659427; called by muse, mutect2, varscan2
- FBLIM1 | c.327G>A p.P109= | Silent (SNP) | VAF 17/32 reads (53%) | catalogued as rs138682032; called by muse, mutect2, varscan2
- GAK | c.2127G>A p.V709= | Silent (SNP) | VAF 48/129 reads (37%) | catalogued as rs377594780; called by muse, mutect2, varscan2
- IL4I1 | c.1650A>C p.P550= | Silent (SNP) | VAF 41/145 reads (28%) | catalogued as COSV55577208; called by muse, mutect2, varscan2
- LRP5 | c.2235G>A p.A745= | Silent (SNP) | VAF 36/95 reads (38%) | catalogued as rs750492852, COSV53711714; called by muse, mutect2, varscan2
- MAG | c.1842G>A p.T614= | Silent (SNP) | VAF 30/94 reads (32%) | catalogued as rs768107293, COSV62699113; ClinVar: likely benign; called by muse, mutect2, varscan2
- MS4A14 | c.1179C>T p.H393= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as rs753050956, COSV100280497, COSV55733354; called by muse, mutect2, varscan2
- OPN1SW | c.348A>T p.V116= | Silent (SNP) | VAF 47/368 reads (13%) | catalogued as COSV50822594; called by muse, mutect2, varscan2
- OR5H2 | c.855C>T p.I285= | Silent (SNP) | VAF 29/81 reads (36%) | catalogued as rs1265919655, COSV62350037; called by muse, mutect2, varscan2
- PIP5K1B | c.1572C>T p.N524= | Silent (SNP) | VAF 72/239 reads (30%) | catalogued as COSV55242102; called by muse, mutect2, varscan2
- SGCD | c.780C>T p.F260= (on ENST00000435422 / NM_001128209.2; = p.F261= on NM_000337.5) | Silent (SNP) | VAF 81/233 reads (35%) | catalogued as rs768741617, COSV61903980, COSV61905794; called by muse, mutect2, varscan2
- SLIT1 | c.1329C>T p.C443= | Silent (SNP) | VAF 31/50 reads (62%) | catalogued as rs745617207, COSV56583132; called by muse, mutect2, varscan2
- TMEM132D | c.3195C>T p.I1065= | Silent (SNP) | VAF 116/336 reads (35%) | catalogued as rs776600445, COSV67158685; called by muse, mutect2, varscan2
- TTC26 | c.1050A>G p.G350= | Silent (SNP) | VAF 60/227 reads (26%) | catalogued as COSV58269681; called by muse, mutect2, varscan2
- TUBB1 | c.1062C>T p.C354= | Silent (SNP) | VAF 34/122 reads (28%) | catalogued as rs775221566, COSV53885972; called by muse, mutect2, varscan2
- DNM1L | c.*1446C>T | 3'UTR (SNP) | VAF 10/26 reads (38%) | catalogued as rs761066696, COSV99846040; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.400+6898C>T | Intron (SNP) | VAF 246/454 reads (54%) | catalogued as rs766745626, COSV57113200; called by muse, mutect2, varscan2
- PSMG2 | c.-2C>T | 5'UTR (SNP) | VAF 10/49 reads (20%) | catalogued as COSV50865579; called by muse, mutect2, varscan2
